Surgical pathology report (de-identified scan), TCGA case TCGA-NP-A5H7, project TCGA-KICH (Kidney Chromophobe), tissue source site International Genomics Consortium, specimen TCGA-NP-A5H7-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE: RECEIVED DATE:

COPY TO: [REDACTED], [REDACTED]

Pre-Op Diagnosis

Right renal mass

Post-Op Diagnosis

Pending pathology

Clinical History

Nothing indicated on requisition

Gross Description:

Received labeled "[REDACTED] - right kidney" is an 868 gram nephrectomy specimen consisting of a 20.3 x 12.8 x 6.1 cm kidney and a moderate amount of attached perinephric fat. There are several tubular structures tied off at the hilum consistent with probable ureter renal vein and renal artery. The cut surface of the kidney consists of a 13.8 x 11.7 x 9.1 cm diffuent tan orange to red green mass which abuts the inked outer surface of the kidney. The mass does not appear to involve the perinephric fat. There is a minimal amount of residual tan red parenchyma. The cortical medullary junction is well defined. The urothelium is glistening gray white. No additional lesions are identified. The adrenal gland is not present. No obvious lymph nodes are identified. The specimen is inked, serially sectioned, and representative sections are submitted as labeled: A - ureteral vascular margins (en face), B and C - mass to outer surface of kidney, D - mass to hilar adipose tissue, E - mass to uninvolved parenchyma, F and G - random mass, H - inked perinephric fat, I - uninvolved parenchyma. Also received in the same container is a green and yellow cassette labeled for genomic research studies.

Microscopic Description:

Reviewed are slides labeled [REDACTED]

ICD-O-3

Carcinoma, renal cell

Chromophobe type 8317/3

Site: (R) Kidney NOS C64.9

JW 12/24/12

[page 2 of 3]
Final Diagnosis

Kidney, right, radical nephrectomy:

Tumor characteristics:

Specimen integrity: Intact.

Histologic type: Chromophobe renal cell carcinoma.

Tumor site: Right kidney, extensive involvement.

Tumor focality: Unifocal.

Tumor size: 13.8 x 11.7 x 9.1 cm.

Macroscopic extent of tumor: Confined to kidney.

Microscopic extent of tumor: Confined to kidney.

Nuclear grade: Fuhrman grade: 4/4

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified in sections examined.

Sarcomatoid features: Not identified; microscopic areas of necrosis present.

Surgical margin status: Surgical margins appear to be free of malignancy in sections examined.

Lymph node status: Not applicable (none submitted). PAS 9
SPC-A

Stage: pT2bNX

CPT: 88309, 88342 x4, 88313

Comments

Histologic sections from the neoplasm demonstrate a tumor composed of moderately pleomorphic cells with abundant pale cytoplasm and large pleomorphic nuclei. The cells are arranged in small clusters as well as large sheets. Focal areas of necrosis are noted.

To better characterize this neoplasm, a panel of immunohistochemical and histochemical stains are performed with working controls. The cells are variably positive for CK7 with large areas strongly and diffusely positive; other areas demonstrate more variable positivity. The cells are weakly positive for CD10. The cells are negative for vimentin and cytokeratin AE1/AE3. Hale's colloidal iron is weakly positive in the majority of the cells.

The overall histologic, histochemical, and immunohistochemical features of this neoplasm are most consistent with chromophobe renal cell carcinoma. The differential diagnosis includes oncocytoma, however, given the nuclear features (binuclear forms, abundant resinoid nuclei) distinct cytoplasmic borders, strong CK7 staining, and positive, though weakly positive, colloidal iron staining, this neoplasm is best classified as a chromophobe renal cell carcinoma. Clinical correlation is recommended.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED] who concurs with the diagnosis.

This report has been finalized at the [REDACTED]

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical

[page 3 of 3]
laboratory testing.

<Sign Out Dr. Signature>

move to chronophoba
by 12/8/12

Source: NCI Genomic Data Commons file 0dc66b8a-3e7d-4467-9555-4919416fa836 (TCGA-NP-A5H7.A2B8AEF3-3B3C-4094-A54B-C0F01BECA089.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).